HCMI case HCM-CSHL-0462-D05 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4eea6e7d-a49d-49c5-b849-48665b79548b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1968; Vital status: Alive.

Diagnoses (1)
1. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; ICD-10 code: D05.11; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: Premalignant; Age at diagnosis: 49.1 years (17,939 days); AJCC staging edition: 8th; AJCC clinical stage: Stage 0; AJCC pathologic T: Tis (DCIS); AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0; Tumor grade: GX; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 76 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 798 days (2.2 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 0, day 354.

Molecular and laboratory tests
- ESR1 (IHC): 8; Specialized molecular test: Allred score.
- PGR (IHC): Positive.

Other clinical attributes
- Day 0: Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 129.3 kg; Height: 165.1 cm; BMI: 47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0462-D05-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0462-D05-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-CSHL-0462-D05-31B-01-S1-HE: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 55; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0462-D05-31B-01-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-CSHL-0462-D05-85T: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
